Gene-level copy-number profile of tumor specimen HCM-BROD-0762-C49-01A from HCMI case HCM-BROD-0762-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Abdominal fibromatosis; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 15.9 years (5,799 days).
Specimen HCM-BROD-0762-C49-01A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 37055441-dbfe-4410-a725-72ff91057de1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0762-C49-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/b32c7aeb-7da9-4d84-8523-0c946cf090cc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 26; copy number 2: 58,369; copy number 3: 4; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:41,829,692–41,835,950, 2 genes, copy number 5: HNRNPA1P52, AC243967.3.

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
